Somatic mutation profile of tumor specimen 8d7fc1ef-a0ac-44bb-8381-1444a0 (aliquot 8d7fc1ef-a0ac-44bb-8381-1444a0_D6_1) from CPTAC case 11BR025, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.4 years (28,257 days).
Specimen 8d7fc1ef-a0ac-44bb-8381-1444a0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 104aecca-5497-422e-a178-c4c7858ca114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen af148751-8390-4acc-8ef9-8cb829 (Blood Derived Normal), aliquot af148751-8390-4acc-8ef9-8cb829_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc702e9d-fd56-4245-bb19-7dbb14a6fb1b

The open-access MAF lists 55 somatic variants for this specimen: 32 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Intron 5, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDC | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 173/359 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853212, CM984683, COSV63564689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 84/718 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775213299, COSV52374028; called by muse, varscan2
- ARHGAP23 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs917833409; called by muse, mutect2, varscan2
- ARHGAP6 | c.1297C>G p.R433G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57293087; called by muse, mutect2, varscan2
- CCIN | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1007899869, COSV58724132; called by muse, mutect2, varscan2
- CHTOP | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52679789; called by muse, mutect2, varscan2
- CSMD3 | c.8594G>C p.G2865A (on ENST00000297405 / NM_001363185.1; = p.G2696A on NM_052900.3) | Missense Mutation (SNP) | VAF 48/600 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52216230; called by muse, mutect2
- JPH2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1304705938; called by muse, mutect2, varscan2
- NFKBIE | c.682G>A p.E228K (on ENST00000275015; = p.E89K on NM_004556.3) | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs970631698; called by muse, mutect2, varscan2
- NIPBL | c.4075G>T p.D1359Y | Missense Mutation (SNP) | VAF 122/209 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1328939808; called by muse, mutect2, varscan2
- RASA1 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 97/322 reads (30%) | catalogued as COSV56923956, COSV56924286; called by muse, mutect2, varscan2
- RCOR2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 58/276 reads (21%) | catalogued as rs745567946, COSV56851616; called by muse, mutect2, varscan2
- RTL9 | c.17A>T p.H6L | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV101511629; called by muse, mutect2, varscan2
- TFR2 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs370714327; called by mutect2, varscan2
- ACADVL | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 88/619 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BANK1 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- BICDL2 | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CALML5 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K1 | c.3479del p.K1160Rfs*12 | Frame Shift Del (DEL) | VAF 139/307 reads (45%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.4307G>T p.G1436V | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDNF | c.1048A>T p.I350L | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- NHS | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RAP1GAP2 | c.1448A>G p.D483G | Missense Mutation (SNP) | VAF 109/201 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIMKLA | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- SELPLG | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 234/378 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SETD3 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SIGLEC9 | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SOBP | c.2500C>A p.P834T | Missense Mutation (SNP) | VAF 91/479 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TAF10 | c.522C>G p.C174W | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TBX3 | c.548_549dup p.M184Gfs*25 | Frame Shift Ins (INS) | VAF 44/278 reads (16%) | called by mutect2, pindel, varscan2
- TNKS | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ZNF681 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); called by mutect2, varscan2
- ADAM11 | c.39G>A p.L13= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CADM3 | c.369C>T p.L123= (on ENST00000368125 / NM_001127173.3; = p.L157= on NM_021189.5) | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1557936347, COSV63684168, COSV63686685; called by muse, mutect2, varscan2
- COL4A1 | c.2271G>A p.K757= | Silent (SNP) | VAF 10/241 reads (4%) | catalogued as COSV65422268; called by muse, mutect2
- FGFBP3 | c.582G>T p.P194= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2, varscan2
- FOXO6 | c.1338C>G p.L446= | Silent (SNP) | VAF 15/19 reads (79%) | catalogued as rs1272366857; called by muse, mutect2, varscan2
- FTMT | c.453C>T p.D151= | Silent (SNP) | VAF 46/324 reads (14%) | catalogued as COSV58420725; called by muse, mutect2, varscan2
- HAS2 | c.1572C>T p.V524= | Silent (SNP) | VAF 104/614 reads (17%) | called by muse, mutect2, varscan2
- HM13 | c.48C>T p.G16= | Silent (SNP) | VAF 45/211 reads (21%) | called by muse, mutect2, varscan2
- PLBD1 | c.1563C>T p.R521= | Silent (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- SUPT3H | c.759C>T p.D253= (on ENST00000371460 / NM_181356.3; = p.D242= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- TBL3 | c.1023G>T p.R341= | Silent (SNP) | VAF 140/538 reads (26%) | catalogued as COSV100225060; called by muse, mutect2, varscan2
- TLN1 | c.4476C>G p.L1492= | Silent (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- TMEM132E | c.27C>T p.G9= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.177T>C p.L59= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- ZMAT1 | c.432C>A p.V144= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100858943; called by muse, mutect2, varscan2
- C22orf42 | c.493+78C>T | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- MBNL1 | c.1111-1077G>T | Intron (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- NCF4 | c.758+22G>C | Intron (SNP) | VAF 198/510 reads (39%) | called by muse, mutect2, varscan2
- PFKP | c.1684-17C>T | Intron (SNP) | VAF 30/134 reads (22%) | catalogued as rs183922881; called by muse, mutect2, varscan2
- PIPSL | n.1897C>T | RNA (SNP) | VAF 82/451 reads (18%) | catalogued as rs565684528; called by muse, mutect2, varscan2
- RIN1 | c.*25C>T | 3'UTR (SNP) | VAF 37/157 reads (24%) | catalogued as rs1265738292, COSV60925560; called by muse, mutect2, varscan2
- SH3BGR | c.*91G>A | 3'UTR (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- TBCK | c.1171-711A>G | Intron (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
